Somatic mutation profile of tumor specimen MP2PRT-PATBZH-TMP1-A (aliquot MP2PRT-PATBZH-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATBZH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,699 days).
Specimen MP2PRT-PATBZH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f33de6b-6015-4368-8a1f-53d45e0e46a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBZH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBZH-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b726c0b-d13a-4afd-b523-c12320e026bb

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 3, Frame Shift Ins 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 58/105 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 33/154 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ART1 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 211/436 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV51705840; called by muse, mutect2, varscan2
- CLCN6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 255/540 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100411920; called by muse, mutect2, varscan2
- EPHA5 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV56632749, COSV56676910; called by muse, mutect2
- GPC5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 85/613 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as rs1264953563; called by muse, mutect2, varscan2
- HEG1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs776148618; called by muse, mutect2, varscan2
- MAZ | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 131/703 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.561); catalogued as rs995948460, COSV99360870; called by muse, mutect2, varscan2
- NAV3 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 170/388 reads (44%) | catalogued as rs1480204948, COSV57080262, COSV57106346, COSV99887406; called by muse, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 148/358 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBA2 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as COSV99875680; called by muse, mutect2, varscan2
- ADAM17 | c.33_34insTC p.V12Sfs*45 | Frame Shift Ins (INS) | VAF 290/711 reads (41%) | called by mutect2, pindel, varscan2
- CDC37 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 174/375 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- COL17A1 | c.837A>C p.S279= | Splice Region (SNP) | VAF 117/262 reads (45%) | called by muse, mutect2, varscan2
- DOT1L | c.2490_2491insGG p.R831Gfs*21 | Frame Shift Ins (INS) | VAF 103/635 reads (16%) | called by mutect2, pindel, varscan2
- MCOLN3 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 106/219 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC12 | c.4036G>A p.E1346K (on ENST00000379442; = p.E1203K on NM_001164462.1) | Missense Mutation (SNP) | VAF 20/861 reads (2%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2
- NRXN3 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 118/552 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- OR2A42 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- POC1B | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 137/295 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SACS | c.11554C>T p.Q3852* | Nonsense Mutation (SNP) | VAF 151/305 reads (50%) | called by muse, mutect2, varscan2
- SORCS1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 136/756 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SP8 | c.155C>G p.S52* (on ENST00000361443 / NM_198956.4; = p.S70* on NM_182700.6) | Nonsense Mutation (SNP) | VAF 190/398 reads (48%) | called by muse, mutect2, varscan2
- TSGA10 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMPR1B | c.672T>A p.R224= | Silent (SNP) | VAF 209/463 reads (45%) | called by muse, mutect2, varscan2
- OTOP3 | c.1005C>T p.C335= | Silent (SNP) | VAF 241/501 reads (48%) | catalogued as rs758257452, COSV60914931; called by muse, mutect2, varscan2
- PCDHA6 | c.1629G>A p.P543= | Silent (SNP) | VAF 368/805 reads (46%) | catalogued as COSV65344271; called by muse, mutect2, varscan2
- ZNF429 | c.192G>A p.K64= | Silent (SNP) | VAF 38/412 reads (9%) | called by muse, mutect2
- REXO1L1P | n.1553G>A | RNA (SNP) | VAF 62/1800 reads (3%) | catalogued as rs146084583; called by muse, mutect2
